Gene-level copy-number profile of tumor specimen TCGA-AD-6901-01A from TCGA case TCGA-AD-6901, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cecum; Age at diagnosis: 78.2 years (28,579 days).
Specimen TCGA-AD-6901-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.620d61a5-531b-4d11-b5c7-1bfdea480f5b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AD-6901-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9e06481e-fb85-48c5-a3f9-13389c09f076

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 1,406; copy number 2: 29,745; copy number 3: 20,772; copy number 4: 1,701; copy number 5: 2,786; copy number 6: 3,363; copy number 11: 11; copy number 19: 28.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AD-6901-01A-11D-1923-01): tumor purity 0.57, ploidy 2.72, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:115,764,099–115,764,819, 1 gene: PGAM4P2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 6,188 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:70,972–65,401,136, 1,210 genes, copy number 5 (broad region; genes not listed).
- chr8:41,653,220–41,896,762, 1 gene, copy number 11 (within-gene range 1–11): ANK1.
- chr8:41,803,349–42,171,673, 10 genes, copy number 11: Y_RNA, AC027702.1, RN7SL149P, KAT6A, AC090571.1, AC103724.1, AC103724.2, AC103724.4, AC103724.3, AP3M2.
- chr9:14,475–22,128,103, 321 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr9:25,780,032–43,045,120, 431 genes, copy number 5–6 (broad region; genes not listed).
- chr11:167,784–56,543,281, 1,280 genes, copy number 6–19 (broad region; genes not listed).
- chr13:18,467,172–114,337,626, 1,391 genes, copy number 6 (broad region; genes not listed).
- chr19:5,830,408–7,629,545, 88 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr20:87,250–16,053,197, 293 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr20:15,280,764–64,313,132, 1,163 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,406. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
